Somatic mutation profile of tumor specimen MMRF_1295_1_BM_CD138pos (aliquot MMRF_1295_1_BM_CD138pos_T2_TSE61_K03766) from MMRF case MMRF_1295, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.7 years (23,990 days).
Specimen MMRF_1295_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60d2f51d-2ff9-43fb-8642-2a2abd7b33b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1295_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1295_1_PB_Whole_C1_TSE61_K03767; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73aea1af-a937-4ef7-838f-0bcbccc0d4f2

The open-access MAF lists 79 somatic variants for this specimen: 31 protein-altering or splice-affecting, 11 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, 3'UTR 23, Silent 11, 5'UTR 6, 3'Flank 3, RNA 3, Intron 2, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADGRD1 | c.2223C>G p.I741M | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.247); catalogued as rs1338367550; called by muse, mutect2, varscan2
- ANK3 | c.12265C>T p.R4089W (on ENST00000280772 / NM_001320874.2; = p.R610W on NM_001149.3) | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1241719626, COSV55067280; called by muse, mutect2, varscan2
- BDP1 | c.5587G>T p.A1863S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.112); catalogued as rs1386527502; called by muse, mutect2
- CDIPT | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs752207139; called by muse, mutect2, varscan2
- FCN3 | c.596G>C p.R199P | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV54641651; called by muse, mutect2, varscan2
- FMO5 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs782619685; called by muse, mutect2, varscan2
- GAS2L2 | c.2312T>C p.I771T | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1256453755; called by muse, mutect2, varscan2
- MCEE | c.269A>G p.N90S | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs758798866; called by muse, mutect2, varscan2
- NDUFS3 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 91/206 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs201371939, COSV55456210; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PARP8 | c.944A>G p.H315R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.026); catalogued as rs1171277291; called by muse, mutect2, varscan2
- PCDHB14 | c.1582G>C p.E528Q | Missense Mutation (SNP) | VAF 199/419 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.72); catalogued as rs564904617; called by muse, mutect2, varscan2
- PCDHB5 | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 127/275 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs1392821397; called by muse, mutect2, varscan2
- PEX1 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as CM111100; called by muse, mutect2, varscan2
- TMCO6 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 105/205 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs1241785125; called by muse, mutect2, varscan2
- UGCG | c.78T>G p.H26Q | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as rs779325294; called by muse, mutect2, varscan2
- AKAP9 | c.1648A>T p.T550S | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- ARHGEF7 | c.1299T>A p.D433E (on ENST00000375741 / NM_001113511.2; = p.D255E on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- COL11A1 | c.214A>T p.T72S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- COTL1 | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 119/224 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FZD10 | c.956T>A p.F319Y | Missense Mutation (SNP) | VAF 44/434 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGFBP2 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 93/180 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- IPO4 | c.2483_2485del p.D828del | In Frame Del (DEL) | VAF 60/86 reads (70%) | called by pindel, varscan2
- KCNT2 | c.1340T>G p.L447* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- MINDY2 | c.363_364del p.H121Qfs*60 | Frame Shift Del (DEL) | VAF 25/56 reads (45%) | called by mutect2, pindel*, varscan2*
- PLA2G6 | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PLG | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PRRC2B | c.6667A>G p.K2223E | Missense Mutation (SNP) | VAF 86/198 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RANBP6 | c.1864dup p.I622Nfs*19 | Frame Shift Ins (INS) | VAF 39/95 reads (41%) | called by mutect2, pindel, varscan2
- SEMA3F | c.148T>C p.F50L | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TRPV2 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ELMO3 | c.649C>T p.L217= (on ENST00000652269; = p.L164= on NM_024712.5) | Silent (SNP) | VAF 83/242 reads (34%) | called by muse, mutect2, varscan2
- FASTKD2 | c.1860T>G p.L620= | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- HECW1 | c.1647C>T p.A549= | Silent (SNP) | VAF 125/239 reads (52%) | called by muse, mutect2, varscan2
- LILRB2 | c.789C>T p.D263= | Silent (SNP) | VAF 143/370 reads (39%) | called by muse, varscan2
- MAP6 | c.1842C>T p.V614= | Silent (SNP) | VAF 86/184 reads (47%) | catalogued as rs189313720; called by muse, mutect2, varscan2
- MPDZ | c.4521C>A p.I1507= | Silent (SNP) | VAF 49/134 reads (37%) | called by muse, mutect2, varscan2
- MYLK | c.618T>C p.R206= | Silent (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- NUTM2G | c.156C>T p.G52= | Silent (SNP) | VAF 104/371 reads (28%) | called by muse, mutect2, varscan2
- SLC9C1 | c.1926C>T p.S642= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs200055695; called by muse, mutect2, varscan2
- TMEM266 | c.753C>T p.I251= | Silent (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- ZNF135 | c.51G>A p.E17= | Silent (SNP) | VAF 44/115 reads (38%) | called by muse, mutect2, varscan2
- CCDC50 | c.*4274G>T | 3'UTR (SNP) | VAF 3/51 reads (6%) | called by muse, mutect2
- CDC73 | c.*3429T>G | 3'UTR (SNP) | VAF 37/110 reads (34%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*4474G>A | 3'UTR (SNP) | VAF 29/85 reads (34%) | catalogued as COSV57058621; called by muse, mutect2
- CPXCR1 | c.-169G>A | 5'UTR (SNP) | VAF 58/77 reads (75%) | catalogued as rs1227798912; called by muse, mutect2, varscan2
- CSMD3 | c.*841G>T | 3'UTR (SNP) | VAF 79/174 reads (45%) | called by muse, mutect2, varscan2
- DIP2A | c.*367T>A | 3'UTR (SNP) | VAF 47/141 reads (33%) | called by muse, mutect2, varscan2
- EDAR | c.*1575G>A | 3'UTR (SNP) | VAF 37/72 reads (51%) | called by muse, mutect2, varscan2
- EXO5 | c.*363C>T | 3'UTR (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2, varscan2
- FOXO3 | c.*1420A>G | 3'UTR (SNP) | VAF 236/576 reads (41%) | called by muse, mutect2, varscan2
- GPATCH8 | c.*188T>G | 3'UTR (SNP) | VAF 86/173 reads (50%) | called by muse, mutect2, varscan2
- GPR39 | c.*793G>T | 3'UTR (SNP) | VAF 54/137 reads (39%) | catalogued as rs1168291681; called by muse, mutect2, varscan2
- HADHA | c.-14C>T | 5'UTR (SNP) | VAF 109/230 reads (47%) | catalogued as rs1310208711; called by muse, mutect2, varscan2
- HOXC12 | chr12:53962349 C>G | 3'Flank (SNP) | VAF 56/111 reads (50%) | called by muse, mutect2, varscan2
- IPO9 | c.*2546C>G | 3'UTR (SNP) | VAF 23/80 reads (29%) | called by muse, mutect2, varscan2
- KCNIP4 | c.61+96118C>T | Intron (SNP) | VAF 34/63 reads (54%) | catalogued as rs1245624997; called by muse, mutect2, varscan2
- KIAA1191 | c.-327A>T | 5'UTR (SNP) | VAF 49/111 reads (44%) | called by muse, mutect2, varscan2
- LINC01551 | n.1254+18478G>A | Intron (SNP) | VAF 46/49 reads (94%) | called by muse, mutect2, varscan2
- LINC01973 | n.932T>G | RNA (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- LYPD6B | c.*388T>C | 3'UTR (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- MEF2A | c.*2942G>A | 3'UTR (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- MIR19B1 | n.39T>A | RNA (SNP) | VAF 126/259 reads (49%) | called by muse, mutect2, varscan2
- MIR6073 | chr11:15966568 T>A | 3'Flank (SNP) | VAF 131/275 reads (48%) | called by muse, mutect2, varscan2
- NEK4 | c.*363_*364del | 3'UTR (DEL) | VAF 39/138 reads (28%) | called by mutect2, pindel, varscan2
- NFIX | c.*3312_*3319del | 3'UTR (DEL) | VAF 16/32 reads (50%) | catalogued as rs932275505; called by mutect2, varscan2
- NRXN3 | chr14:79862496 A>T | 3'Flank (SNP) | VAF 90/94 reads (96%) | called by muse, mutect2, varscan2
- PLXNA4 | c.*980_*982del | 3'UTR (DEL) | VAF 99/203 reads (49%) | called by pindel, varscan2
- PROSER2 | c.*1265C>T | 3'UTR (SNP) | VAF 91/189 reads (48%) | called by muse, mutect2, varscan2
- RELCH | c.-56G>C | 5'UTR (SNP) | VAF 54/144 reads (38%) | catalogued as COSV99902905; called by muse, mutect2, varscan2
- RPA4 | c.-3A>G | 5'UTR (SNP) | VAF 35/35 reads (100%) | called by muse, mutect2, varscan2
- RPSAP14 | n.157T>G | RNA (SNP) | VAF 78/89 reads (88%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*87dup | 3'UTR (INS) | VAF 58/124 reads (47%) | catalogued as rs913511703; called by mutect2, varscan2
- SEPTIN7 | c.-22T>C | 5'UTR (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- SYDE1 | c.*837C>T | 3'UTR (SNP) | VAF 30/61 reads (49%) | catalogued as rs977067150; called by muse, mutect2, varscan2
- UBFD1 | c.*2461_*2481del | 3'UTR (DEL) | VAF 101/205 reads (49%) | called by mutect2, pindel, varscan2
- UFD1 | c.*451T>C | 3'UTR (SNP) | VAF 50/94 reads (53%) | called by muse, mutect2, varscan2
- ZBTB10 | c.*2065A>T | 3'UTR (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- ZKSCAN1 | c.*2179T>C | 3'UTR (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
